Gene-level copy-number profile of tumor specimen C3L-05290-01 from CPTAC case C3L-05290, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.6 years (26,889 days).
Specimen C3L-05290-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 297c3dea-b035-4926-a58b-7a6d100202b3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05290-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/aab4ae59-0a9e-4ca5-ae7a-b9eb98e45f85

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 11,318; copy number 2: 32,823; copy number 3: 12,346; copy number 4: 1,908; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:35,724,759–35,725,142, 1 gene: MRPL50P1.
- chr16:28,599,241–28,604,519, 2 genes: AC020765.3, AC020765.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:53,776,048–53,881,051, 3 genes, copy number 5: LINC02105, ASS1P9, AC025175.1.

Autosomal genes at a single copy (total copy number 1): 11,317. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
